Somatic mutation profile of tumor specimen TCGA-D7-8570-01A (aliquot TCGA-D7-8570-01A-11D-2340-08) from TCGA case TCGA-D7-8570, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 44.2 years (16,150 days).
Specimen TCGA-D7-8570-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ef55a19-d71b-4db5-b74a-6700f197e07c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-8570-10A (Blood Derived Normal), aliquot TCGA-D7-8570-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2bc2eb4e-9323-40c6-a7ae-cf0fff5164df

The open-access MAF lists 121 somatic variants for this specimen: 87 protein-altering or splice-affecting, 31 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 31, Nonsense Mutation 4, Frame Shift Del 4, RNA 2, In Frame Del 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA10 | c.725G>C p.G242A | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.377); catalogued as rs564915997, COSV52222280, COSV52227382; called by muse, mutect2, varscan2
- AL592490.1 | c.870C>G p.I290M | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV69426297; called by muse, mutect2, varscan2
- ARVCF | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs779199880, COSV54266925; called by muse, mutect2
- AURKC | c.828C>A p.Y276* (on ENST00000302804 / NM_001015878.2; = p.Y242* on NM_003160.3) | Nonsense Mutation (SNP) | VAF 7/92 reads (8%) | catalogued as COSV57138650; called by muse, mutect2
- BCL9L | c.2576T>C p.M859T | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs531414289, COSV52684435; called by muse, mutect2, varscan2
- BIRC2 | c.346C>G p.L116V | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.176); catalogued as COSV57161463; called by muse, mutect2, varscan2
- BTAF1 | c.3192T>A p.N1064K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV56434182; called by muse, mutect2, varscan2
- CACNA1H | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764822234, COSV61990780; called by muse, mutect2, varscan2
- CAMTA2 | c.2852C>T p.P951L | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs765108075, COSV52777443; called by muse, mutect2, varscan2
- CASP8 | c.1389G>C p.M463I (on ENST00000432109 / NM_033355.3; = p.M480I on NM_001228.4) | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV51850971; called by muse, mutect2
- CDH8 | c.2345G>A p.R782H | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs772878546, COSV54867033; called by muse, mutect2, varscan2
- CDH9 | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV50288297, COSV50450406; called by muse, mutect2, varscan2
- CDK14 | c.521C>T p.T174I (on ENST00000380050 / NM_001287135.2; = p.T156I on NM_012395.3) | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV56035228; called by muse, mutect2
- CENPF | c.5105T>A p.L1702H | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.143); catalogued as COSV65275055; called by muse, mutect2, varscan2
- CENPN | c.874del p.R292Dfs*3 | Frame Shift Del (DEL) | VAF 10/76 reads (13%) | catalogued as COSV59905354; called by mutect2, pindel, varscan2
- CEP63 | c.1483C>G p.L495V | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.319); catalogued as rs535694503, COSV59676438; called by muse, mutect2, varscan2
- CLCNKA | c.1981C>T p.R661W | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as rs757979867, COSV58891626; called by muse, mutect2, varscan2
- CLIP4 | c.1452A>T p.E484D | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs543402143, COSV60749238; called by muse, mutect2
- CLSTN1 | c.879C>G p.D293E (on ENST00000377298 / NM_001009566.3; = p.D283E on NM_014944.4) | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV63648067; called by muse, mutect2
- CNOT3 | c.2038G>T p.G680C | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55363348; called by muse, mutect2, varscan2
- CNTLN | c.4020A>G p.I1340M | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.64); catalogued as COSV52079234; called by muse, mutect2, varscan2
- COL6A3 | c.8431C>T p.R2811C | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371361651; called by muse, mutect2, varscan2
- CPSF3 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1035362399, COSV53008489; called by muse, mutect2, varscan2
- CYP2S1 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs773132133, COSV59506131; called by muse, mutect2, varscan2
- DNAH2 | c.2479C>T p.R827W | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs760771496, COSV66718028; called by muse, mutect2, varscan2
- DNAH9 | c.10078G>A p.V3360M | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs550765729, COSV52350059; called by muse, mutect2, varscan2
- EFCAB6 | c.3982C>A p.L1328I | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV53063490; called by muse, mutect2, varscan2
- EMILIN2 | c.2896G>T p.V966L | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs368956752, COSV54424794; called by muse, mutect2, varscan2
- EPB41L1 | c.873G>C p.K291N | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV52437935; called by muse, mutect2, varscan2
- EYS | c.419G>T p.W140L | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.271); catalogued as COSV60985879; called by muse, mutect2, varscan2
- FGG | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.486); catalogued as COSV60195401; called by muse, mutect2, varscan2
- FMNL1 | c.2191C>T p.R731C | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs377137839; called by muse, mutect2, varscan2
- FZD1 | c.1870G>A p.G624S | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.572); catalogued as COSV55310557, COSV99842837; called by muse, mutect2, varscan2
- GFRA1 | c.557T>C p.V186A | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.471); catalogued as COSV62605793; called by muse, varscan2
- GGTLC1 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs774521787, COSV53847008, COSV53847834; called by muse, mutect2, varscan2
- GIMAP1 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as rs368249123; called by muse, mutect2, varscan2
- GOLGA1 | c.2156C>G p.A719G | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52346798, COSV99414547; called by muse, mutect2, varscan2
- GRM5 | c.23C>G p.S8* | Nonsense Mutation (SNP) | VAF 7/71 reads (10%) | catalogued as COSV59605551; called by muse, mutect2, varscan2
- HK1 | c.1546G>A p.V516I | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.228); catalogued as COSV53858224; called by muse, mutect2, varscan2
- HOXD4 | c.535C>G p.L179V | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60459905; called by muse, mutect2
- IGFLR1 | c.338G>A p.R113K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV53074769; called by muse, mutect2, varscan2
- INPP4B | c.2456A>T p.K819M | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53725428; called by muse, mutect2, varscan2
- IVD | c.641C>G p.T214R (on ENST00000651168; = p.T211R on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51099218; called by muse, mutect2
- KCTD21 | c.773G>T p.R258L | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV60741135, COSV60741494, COSV60741878; called by muse, mutect2, varscan2
- KMT2D | c.14502A>T p.E4834D | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV56440305; called by muse, mutect2, varscan2
- LRRC52 | c.326G>C p.S109T | Missense Mutation (SNP) | VAF 24/291 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54232202; called by muse, mutect2
- MAL | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV59431452; called by muse, mutect2, varscan2
- MBD5 | c.2743A>T p.N915Y | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV68697058; called by muse, mutect2, varscan2
- NCOR2 | c.4748G>A p.R1583Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1445774603, COSV62298194; called by muse, mutect2
- NUFIP2 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.221); catalogued as COSV56603479; called by muse, mutect2, varscan2
- NUP42 | c.70G>C p.G24R | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.146); catalogued as COSV51729618, COSV99331168; called by muse, mutect2, varscan2
- OPRM1 | c.1177G>T p.E393* | Nonsense Mutation (SNP) | VAF 24/118 reads (20%) | catalogued as COSV57825978; called by muse, mutect2, varscan2
- OR2B3 | c.215G>A p.C72Y | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1249238062, COSV65850948; called by muse, mutect2, varscan2
- OSBPL3 | c.611G>A p.G204D | Missense Mutation (SNP) | VAF 63/265 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV57656738; called by muse, mutect2, varscan2
- OXCT1 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as COSV52171091; called by muse, mutect2
- PARP10 | c.748C>G p.L250V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57297840; called by muse, mutect2, varscan2
- PCDH10 | c.1103G>T p.S368I | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV52094240, COSV52102312; called by muse, mutect2, varscan2
- PCDHB2 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.022); catalogued as rs782344713, COSV52028956; called by muse, mutect2, varscan2
- POM121 | c.1103A>T p.K368M (on ENST00000434423; = p.K103M on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57515710; called by muse, mutect2, varscan2
- PRKCG | c.940C>T p.R314W | Missense Mutation (SNP) | VAF 22/243 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV54727882; called by muse, mutect2
- PSMC1 | c.898G>A p.G300S | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.483); catalogued as COSV54320854; called by muse, mutect2, varscan2
- PTPRJ | c.3230-1G>C p.X1077_splice | Splice Site (SNP) | VAF 5/45 reads (11%) | catalogued as COSV69252322; called by muse, mutect2, varscan2
- RBP4 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV65160234; called by muse, mutect2, varscan2
- SAR1A | c.144C>G p.D48E | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.453); catalogued as COSV64698043; called by muse, mutect2, varscan2
- SCGB2A2 | c.35T>A p.L12H | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57174608; called by muse, mutect2, varscan2
- SCN1A | c.5441A>C p.K1814T (on ENST00000303395 / NM_001202435.3; = p.K1803T on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57670432; called by muse, mutect2, varscan2
- SGCG | c.370G>A p.G124S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.85); catalogued as COSV54560487; called by muse, mutect2, varscan2
- SLC7A8 | c.59A>T p.E20V | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV57554111; called by muse, mutect2, varscan2
- SOCS3 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58270402; called by muse, mutect2, varscan2
- SORL1 | c.6359G>C p.G2120A | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as COSV52754561; called by muse, mutect2
- SPG11 | c.4180T>G p.Y1394D | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.07); catalogued as COSV55995091; called by muse, mutect2, varscan2
- SPTA1 | c.3136C>T p.R1046* | Nonsense Mutation (SNP) | VAF 19/133 reads (14%) | catalogued as COSV63751069; called by muse, mutect2, varscan2
- ST18 | c.1567G>A p.G523R | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.402); catalogued as rs894006203, COSV52494488; called by muse, mutect2, varscan2
- TAS2R20 | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as rs376156307; called by muse, mutect2, varscan2
- TEAD2 | c.494C>A p.S165Y | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.482); catalogued as COSV60874005; called by muse, mutect2
- TLR5 | c.848C>G p.A283G | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as COSV60558029, COSV60559085; called by muse, mutect2
- TRAF3IP3 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766710339, COSV50553156, COSV50563391; called by muse, mutect2, varscan2
- UBE3A | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.048); catalogued as rs780050034, COSV51661727, COSV51664376; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZFPM2 | c.2543A>G p.K848R | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.985); catalogued as COSV65873739; called by mutect2, varscan2
- ZSCAN18 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1555800718, COSV53733122, COSV99559346; called by muse, mutect2, varscan2
- B2M | c.197_201del p.I66Kfs*22 | Frame Shift Del (DEL) | VAF 16/140 reads (11%) | called by mutect2, pindel
- DOCK1 | c.3910T>C p.Y1304H | Missense Mutation (SNP) | VAF 2/14 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.43); called by muse, mutect2
- NBEA | c.2664_2667del p.Q888Hfs*40 | Frame Shift Del (DEL) | VAF 19/160 reads (12%) | called by mutect2, pindel, varscan2
- NT5C3B | c.32C>A p.A11D | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR52J3 | c.721_731del p.T241Sfs*66 | Frame Shift Del (DEL) | VAF 15/157 reads (10%) | called by mutect2, pindel
- SPACA3 | c.365_376del p.T122_F125del | In Frame Del (DEL) | VAF 14/82 reads (17%) | called by mutect2, pindel
- VARS1 | c.709_720del p.E237_K240del | In Frame Del (DEL) | VAF 15/109 reads (14%) | called by mutect2, pindel, varscan2
- ARHGAP17 | c.2097G>T p.R699= (on ENST00000289968 / NM_001006634.3; = p.R621= on NM_018054.6) | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as COSV51507346, COSV51512981; called by muse, mutect2, varscan2
- ASH1L | c.5472C>T p.D1824= | Silent (SNP) | VAF 21/265 reads (8%) | catalogued as COSV64208065; called by muse, mutect2
- B3GLCT | c.1110G>A p.E370= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as COSV58455326; called by muse, mutect2, varscan2
- CMTM5 | c.651C>G p.A217= (on ENST00000339180 / NM_001288746.2; = p.A150= on NM_138460.3) | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as COSV59305953; called by muse, mutect2, varscan2
- EPB41L3 | c.2013G>A p.A671= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as rs375430348; called by muse, mutect2, varscan2
- FLNC | c.4437G>C p.V1479= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as COSV57955909, COSV57955994; called by muse, mutect2, varscan2
- GNL3 | c.846T>G p.V282= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV56477549; called by muse, mutect2, varscan2
- IGHV4-4 | c.42C>A p.P14= | Silent (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
- INSM1 | c.1233C>T p.Y411= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as rs754959370, COSV59604797, COSV59605292; called by muse, mutect2
- IRAK3 | c.939C>G p.A313= | Silent (SNP) | VAF 19/115 reads (17%) | catalogued as COSV54161885; called by muse, mutect2, varscan2
- KIAA1109 | c.4404G>A p.A1468= | Silent (SNP) | VAF 8/95 reads (8%) | catalogued as rs766742592, COSV52673521; called by muse, mutect2
- KIR3DL1 | c.255G>A p.V85= | Silent (SNP) | VAF 19/126 reads (15%) | catalogued as COSV58490824; called by muse, mutect2, varscan2
- KRT12 | c.342G>A p.S114= | Silent (SNP) | VAF 35/217 reads (16%) | catalogued as rs938238185, COSV52430850; called by muse, mutect2, varscan2
- MRPS10 | c.12G>A p.R4= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV50002605; called by muse, mutect2
- MS4A15 | c.78G>A p.P26= | Silent (SNP) | VAF 18/134 reads (13%) | catalogued as rs575190018, COSV61961235; called by muse, varscan2
- MUC16 | c.4461T>C p.A1487= | Silent (SNP) | VAF 40/218 reads (18%) | catalogued as COSV67466807; called by muse, mutect2, varscan2
- MUC5AC | c.453C>T p.S151= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs749675435, COSV62253977; called by muse, mutect2, varscan2
- NIBAN3 | c.510T>A p.P170= | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as COSV56309292; called by muse, mutect2, varscan2
- NTF3 | c.306G>A p.P102= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV58417625; called by muse, mutect2, varscan2
- PFDN5 | c.150G>C p.L50= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs777584358, COSV54475952; called by muse, mutect2, varscan2
- POLE | c.6120G>C p.A2040= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV100267924, COSV57677832, COSV57680383; called by muse, mutect2, varscan2
- PRPF31 | c.18G>A p.E6= | Silent (SNP) | VAF 14/129 reads (11%) | catalogued as rs772745878, CM155010, COSV58085365; called by muse, mutect2, varscan2
- PRSS16 | c.165C>T p.A55= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs368859680; called by muse, mutect2, varscan2
- RBFOX1 | c.234G>A p.A78= | Silent (SNP) | VAF 24/172 reads (14%) | catalogued as rs1490574094, COSV60959172; called by muse, varscan2
- RSF1 | c.2598C>T p.G866= | Silent (SNP) | VAF 19/125 reads (15%) | catalogued as rs752652254, COSV57840034, COSV57841474; called by muse, mutect2, varscan2
- SESN3 | c.451A>C p.R151= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV53584985; called by muse, mutect2, varscan2
- SLCO4A1 | c.159C>T p.D53= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV53890977; called by muse, mutect2, varscan2
- SPHK2 | c.1821C>T p.A607= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV55337532; called by muse, mutect2, varscan2
- TMC8 | c.552C>G p.L184= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as COSV59209692; called by muse, mutect2, varscan2
- ZNF2 | c.1071C>T p.N357= (on ENST00000611147 / NM_001291605.2; = p.N344= on NM_021088.4) | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as COSV54637002; called by muse, mutect2
- ZNF677 | c.177T>C p.S59= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV61720284; called by muse, mutect2, varscan2
- SNORA26 | n.112G>C | RNA (SNP) | VAF 17/113 reads (15%) | called by muse, mutect2, varscan2
- TBRG4 | c.412-216G>A | Intron (SNP) | VAF 4/47 reads (9%) | catalogued as COSV99345489; called by muse, mutect2
- XIST | n.9194T>A | RNA (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
